Gene-level copy-number profile of tumor specimen TCGA-XF-AAN0-01A from TCGA case TCGA-XF-AAN0, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 68.1 years (24,877 days).
Specimen TCGA-XF-AAN0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.a2cfc450-4766-43ef-9d77-3fbb1f0f431a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-AAN0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a04267ed-bdc2-485a-8836-106a044a2bdf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,647; copy number 2: 35,401; copy number 3: 12,275; copy number 4: 494; copy number 6: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-AAN0-01A-11D-A42D-01): tumor purity 0.52, ploidy 3.66, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:17,825,252–17,933,275, 2 genes, copy number 6: AC025277.1, RPL7P47.
- chr16:17,961,597–17,962,370, 1 gene, copy number 6: AC010601.2.

Autosomal genes at a single copy (total copy number 1): 9,267. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
